Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A409, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A409-01A (Primary Tumor).

Patient:

AP Surgical Pathology: Additional Info

Surg Path

CLINICAL HISTORY:

Biopsy of known carcinoma right 10:00 breast. If invasive carcinoma, please obtain ER, PR, EGFR, HER2/Neu by immunohistochemistry; for all 2+ IHC results please do FISH analysis.

GROSS EXAMINATION:

A. "USNCB right breast, five cores 10:00 area". Received in formalin is a 1.7 x 1 x 0.2 cm aggregate of fibrofatty needle core tissue submitted entirely in a mesh bag in block A1.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

DIAGNOSIS:

A. "USNCB RIGHT BREAST, FIVE CORES 10:00 AREA":

INVASIVE ADENOCARCINOMA OF THE BREAST.

HISTOLOGIC TYPE: DUCTAL.

NOTTINGHAM COMBINED HISTOLOGIC GRADE: 3 OF 3.

TUBULE FORMATION SCORE: 3.

NUCLEAR PLEOMORPHISM SCORE: 3.

MITOTIC RATE SCORE: 3.

LYMPHATIC/VASCULAR INVASION: NOT IDENTIFIED.

IN-SITU CARCINOMA: PRESENT.

TYPE OF IN-SITU CARCINOMA: COMEDO.

NUCLEAR GRADE OF IN-SITU CARCINOMA: 3 OF 3.

MICROCALCIFICATIONS: ABSENT.

ESTROGEN/PROGESTERONE RECEPTOR, HER2/NEU, AND EGFR ANALYSIS: PENDING.

PARAFFIN BLOCK NUMBER: A1.

RESULTS WILL BE ISSUED IN AN ADDENDUM.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed:

ADDENDUM 1:

Please see tests.

for results of supplementary

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed:

Performed by:

Attending MD:

Ordering MD:

Reviewed Initial	Date Reviewed: 4/22/12	

4/23/12

ICD-O-3

Carcinoma, Infiltrating ductal NOS
Y500/3

Site: breast, NOS C50.9

7-2-12
PO

Source: NCI Genomic Data Commons file 2391ef83-0690-48ac-8bba-489b75d7c890 (TCGA-B6-A409.CC77BA51-CE5A-4839-A27A-DD8F389A2733.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).